Surgical pathology report (de-identified scan), TCGA case TCGA-VD-A8K9, project TCGA-UVM (Uveal Melanoma), tissue source site University of Liverpool, specimen TCGA-VD-A8K9-01A (Primary Tumor).

[page 1 of 3]
Page 1 of 3

REPORT Tel:

Clinical Consultant & Location

Forename

Sex

Unit No

This Copy For:

SPECIMEN

Left eye

CLINICAL DETAILS

Suspected choroidal melanoma.

MACROSCOPIC DESCRIPTION

Dimensions: Axial 24.3mm, Horizontal 22.8mm, Vertical 23.4mm

Cornea: Horizontal 12.4mm, Vertical 12mm
Description: clearOptic nerve
Length 5.7mm, Diameter 3.6mmOn trans-illumination, a shadow measuring 13.6mm by 13.1mm
is seen laterally.

Plane of section: horizontal

Intraocular description:
On opening, a mostly amelanotic choroidal tumour is seen.Tumour size
LBD 10.5mm, Height 7.3mm

MICROSCOPY

Histologically, the enucleated eye demonstrates a normal anterior segment with an unremarkable cornea, a deep anterior chamber and open angles. The iris leaves are unremarkable. The ciliary muscles showed advanced atrophic changes and there is moderate hyalinisation of the ciliary processes. The lens is cataractous.

In the posterior segment, a small choroidal melanoma can be seen. This is dome-shaped with a retinal detachment. The retina overlying the tumour is atrophic with degenerative changes.

The tumour is pigmented and consists predominantly of

*ICD-O-3
Melanoma, spindle cell, type B 8774/3
Site: Choroid C69.3
JW 1/17/14*

Reported:

Pathologist:

Electronically Verified:

[page 2 of 3]
Department of Pathology

Page 2 of 3

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

spindle cells. The epithelioid cell component is minimal. The melanoma cells are immunoreactive for MelanA and HSP-27 (score 3).

The number of mitoses is moderate approx. 7/40 high power fields.

The microvasculature of the melanoma is prominent, but closed loops are not seen in the tissue planes examined.

The lymphocytic infiltrate within tumour is minimal. Macrophages are scattered throughout the tumour in a mild density.

There is no evidence of scleral invasion or of extraocular growth. The optic nerve is tumour free, and demonstrates mild atrophic changes. The examined vortex veins are free of tumour.

DIAGNOSIS

Choroid melanoma of spindle cell type.

COMMENT

SPECIMEN	2= Eye
TUMOUR PRESENT	Yes
TUMOUR TYPE	1= Melanoma
CELL TYPE	2= Spindle B
CT LOOPS	1= No closed loops
NECROSIS	No
PIGMENTATION	Yes
LYMPHOCYTIC INFILTRATION	No
MITOTIC FREQUENCY	7 /40 HPF
DIFFUSE MELANOMA	Yes
SPREAD	1= No

Reported:

Pathologist:

Electronically Verified:

[page 3 of 3]
Department of Pathology

Page 3 of 3

HISTOPATHOLOGY REPORT Tel:

Surname [REDACTED]	Lab No [REDACTED]	Clinical Consultant & Location [REDACTED]	
Forename(s) [REDACTED]	DOB/Age [REDACTED]	Sex [REDACTED]	
Unit No [REDACTED]	Request Date [REDACTED]		

This Copy For:

CLEARANCE 2= Adequate

HSP-27 POSITIVITY 3= >70%

LARGE DIAMETER 10.5 mm
THICKNESS 7.3 mm

COMMENTS:

Molecular genetic examination of DNA extracted from the tumour cells will be performed using multiplex-ligation dependent probe amplification (MLPA), looking at chromosomes 1, 3, 6 and 8. A supplementary report will follow as soon as these investigations are complete.

SUPPLEMENTARY REPORT

In the meantime, molecular genetic analysis of tumour DNA extracted from the fresh uveal melanoma tissue was performed using the technique termed multiplex ligation-dependent probe amplification (MLPA). These investigations were performed in the

The kit P027 from [REDACTED], which examines for gains or losses in 31 loci on chromosomes 1, 3, 6 and 8, was used. The DNA concentration was measured using [REDACTED] and the quality assessed using multiplex-PCR prior to the MLPA reaction.

The DNA concentration was high and of good quality on assessment. The MLPA reaction was run at least twice on differing occasions, resulting in similar results.

The results of the sequence analysis of the MLPA products is printed on a separate report.

In summary, sequence analysis demonstrated: normal chromosome 1, disomy 3, gains in chromosome 6 and gains in chromosome 8q.

These molecular data require correlation with the clinical and morphological data for metastatic risk assessment.

Reported:

Pathologist:

Electronically Verified:

ILPAA Discrepancy		
Review or Initials	[Signature]	[Signature]

Source: NCI Genomic Data Commons file b7431719-eb0c-42cc-a802-8f405d56d05a (TCGA-VD-A8K9.61A48B84-57BF-4E16-A371-137B18DA0011.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).